FM case AD5124 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/2e111e69-2355-441d-baa3-f1b11780a551

Female, 62.0 years: Melanoma, NOS (ICD-O-3 8720/3) of the skin; metastasis biopsied or resected from the head, face or neck. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
